Somatic mutation profile of tumor specimen C3N-03012-01 (aliquot CPT0226340006) from CPTAC case C3N-03012, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,252 days).
Specimen C3N-03012-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f83c47e-a90d-4f13-9a0d-b5c96a342f0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03012-31 (Blood Derived Normal), aliquot CPT0226380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2428731f-1ace-4b2b-9677-ab09a5e82f12

The open-access MAF lists 407 somatic variants for this specimen: 259 protein-altering or splice-affecting, 90 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 90, Intron 25, Nonsense Mutation 15, 3'UTR 10, 5'UTR 9, RNA 8, Frame Shift Del 7, Splice Region 6, Splice Site 6, In Frame Del 4, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1B | c.1561dup p.Q521Pfs*30 | Frame Shift Ins (INS) | VAF 122/582 reads (21%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, varscan2
- RYR1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 104/539 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057518970, COSV62104015; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADCY2 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1310622653, COSV57890905; called by muse, mutect2, varscan2
- BOC | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 128/387 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs551152491, COSV56354728; called by muse, mutect2, varscan2
- C2CD4D | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 69/350 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757376795; called by muse, mutect2, varscan2
- C9orf131 | c.2977C>T p.Q993* | Nonsense Mutation (SNP) | VAF 48/282 reads (17%) | catalogued as COSV100398275; called by muse, mutect2, varscan2
- CACNA1C | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs377345545, COSV59696262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCR9 | c.301C>G p.L101V (on ENST00000357632 / NM_031200.3; = p.L89V on NM_006641.4) | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100591785; called by muse, mutect2, varscan2
- CFAP36 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59117889; called by muse, mutect2, varscan2
- CNGA3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 119/550 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs374507358; called by muse, mutect2, varscan2
- CNTFR | c.948G>A p.A316= | Splice Region (SNP) | VAF 80/364 reads (22%) | catalogued as rs775346938; called by muse, mutect2, varscan2
- CSPG4 | c.4646G>C p.R1549T | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1222786399; called by muse, mutect2, varscan2
- CXCL14 | c.288C>G p.I96M (on ENST00000337225; = p.I84M on NM_004887.5) | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100463562; called by muse, mutect2, varscan2
- CYP46A1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV55892877, COSV55893155; called by muse, mutect2, varscan2
- DCC | c.3986G>T p.R1329I | Missense Mutation (SNP) | VAF 182/610 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.652); catalogued as COSV71428594; called by muse, varscan2
- DGCR2 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV54223796; called by muse, mutect2, varscan2
- DMD | c.5307C>A p.H1769Q | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CD068544, COSV100820852; called by muse, mutect2
- DNAH6 | c.9415C>A p.L3139I | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99404509; called by muse, mutect2, varscan2
- DNHD1 | c.12610G>A p.D4204N | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV54443062; called by muse, mutect2, varscan2
- ELAVL3 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1185432149; called by muse, mutect2, varscan2
- EML6 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 79/480 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1488834813, COSV62866455; called by muse, mutect2, varscan2
- ENPP1 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 87/482 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV62933686; called by muse, mutect2, varscan2
- FAM43B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 242/902 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100261609, COSV60579713; called by muse, mutect2, varscan2
- FCRL3 | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63842007; called by muse, mutect2, varscan2
- FYCO1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 153/496 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753932842; called by muse, mutect2, varscan2
- GALNT16 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs767361760, COSV61886650; called by muse, mutect2, varscan2
- GPR148 | c.817T>C p.Y273H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59308743; called by muse, mutect2, varscan2
- HGF | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 209/523 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99738480; called by muse, mutect2, varscan2
- HIVEP2 | c.5657A>G p.H1886R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs1206542238; called by muse, varscan2
- HOXD12 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV66832516; called by muse, mutect2, varscan2
- IDI2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 106/196 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs759042155, COSV52988313; called by muse, varscan2
- ITGB5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 108/165 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1412981929, COSV56148511; called by muse, mutect2, varscan2
- ITPRIP | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs776290130, COSV99532381, COSV99532416; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 28/120 reads (23%) | catalogued as rs755650243; called by mutect2, varscan2
- KAT8 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV54895077; called by muse, mutect2, varscan2
- KLRD1 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201683513, COSV60273294; called by muse, mutect2, varscan2
- LHCGR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 150/717 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs979633619, COSV54295551, COSV54300568; called by muse, mutect2, varscan2
- LRRC42 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 83/392 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs373233986; called by muse, mutect2, varscan2
- MED12L | c.4334C>T p.S1445F | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99851354; called by muse, mutect2, varscan2
- MORC1 | c.1392G>T p.E464D | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV51720487; called by muse, mutect2
- MSH6 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 119/715 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as rs63750440, COSV52277030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs964154792; called by muse, mutect2, varscan2
- NDRG2 | c.721C>G p.R241G (on ENST00000298687 / NM_001354570.1; = p.R227G on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53872932; called by muse, mutect2, varscan2
- NFATC2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 101/187 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as rs755934652; called by muse, mutect2, varscan2
- NPAS3 | c.781C>T p.R261C (on ENST00000356141 / NM_001164749.2; = p.R229C on NM_022123.3) | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV60840049; called by muse, mutect2, varscan2
- OR10G9 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 169/291 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as COSV66686951; called by muse, mutect2, varscan2
- PDGFRL | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1350499076, COSV52415618; called by muse, mutect2, varscan2
- PELI1 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774105601, COSV62730369, COSV62730459; called by muse, mutect2, varscan2
- PEX6 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 245/548 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99769405; called by muse, mutect2, varscan2
- PLEC | c.6259C>A p.R2087S (on ENST00000322810 / NM_201380.4; = p.R1977S on NM_000445.5) | Missense Mutation (SNP) | VAF 254/1962 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV100510382; called by muse, mutect2, varscan2
- PNPLA6 | c.1550G>A p.R517Q (on ENST00000414982 / NM_001166111.2; = p.R469Q on NM_006702.5) | Missense Mutation (SNP) | VAF 100/400 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs370094298, COSV55387017; called by muse, mutect2, varscan2
- PRICKLE2 | c.1828+8C>T | Splice Region (SNP) | VAF 42/155 reads (27%) | catalogued as rs1161425717; called by muse, mutect2, varscan2
- PTPN4 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV55299742; called by muse, mutect2, varscan2
- PTPRR | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 94/413 reads (23%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs368662426; called by muse, mutect2, varscan2
- RFPL2 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 153/388 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768072734; called by muse, mutect2, varscan2
- RUNDC3B | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV56697537; called by muse, mutect2, varscan2
- SATB1 | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 134/462 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV58668220, COSV58672213; called by muse, mutect2, varscan2
- SCMH1 | c.1207G>A p.D403N (on ENST00000326197 / NM_001031694.2; = p.D356N on NM_012236.4) | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs779280545; called by muse, mutect2, varscan2
- SDSL | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 54/301 reads (18%) | catalogued as rs771261383, COSV100615238; called by muse, mutect2, varscan2
- SELP | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV55259713; called by muse, mutect2, varscan2
- SEPHS1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100526011; called by muse, mutect2, varscan2
- SHE | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs773502026; called by muse, mutect2, varscan2
- SLC13A1 | c.91C>A p.H31N | Missense Mutation (SNP) | VAF 84/165 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52017560; called by muse, mutect2, varscan2
- SLC46A2 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 140/255 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1390417498; called by muse, mutect2, varscan2
- SMTN | c.2303T>C p.I768T | Missense Mutation (SNP) | VAF 102/490 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1164342862; called by muse, mutect2, varscan2
- SOAT1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs770741362, COSV62653823; called by muse, mutect2, varscan2
- SPTA1 | c.5995C>G p.Q1999E | Missense Mutation (SNP) | VAF 147/863 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100934289; called by muse, mutect2, varscan2
- SUGCT | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV59340901; called by muse, mutect2, varscan2
- SUPT6H | c.4271G>A p.R1424Q | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs771153866; called by muse, mutect2, varscan2
- SYTL1 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs1490201363, COSV100538960; called by muse, mutect2, varscan2
- TECPR1 | c.2164G>T p.V722L | Missense Mutation (SNP) | VAF 278/2926 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1276627987; called by muse, mutect2
- TIAM1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs758268963; called by muse, mutect2, varscan2
- TJP1 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.107); catalogued as rs754602712, COSV62046420; called by muse, mutect2, varscan2
- TNFSF9 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 206/840 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1047364125; called by muse, varscan2
- TNRC6B | c.98C>G p.T33R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57300201; called by muse, mutect2
- TPGS1 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 114/499 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs906358304; called by muse, mutect2, varscan2
- TRPM7 | c.3025C>A p.L1009I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100539440; called by muse, mutect2, varscan2
- VLDLR | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66074069; called by muse, mutect2, varscan2
- ZC3H4 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.687); catalogued as rs762940554; called by muse, mutect2, varscan2
- ZDHHC6 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs201056784; called by muse, mutect2, varscan2
- ZER1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 99/385 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52566857; called by muse, mutect2, varscan2
- ZIC1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 98/549 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51551496; called by muse, mutect2, varscan2
- ZNF491 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.043); catalogued as rs151175533, COSV104404299; called by muse, mutect2
- ZNF564 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs746913595; called by muse, mutect2, varscan2
- ZNF624 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 47/389 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV60941699; called by muse, mutect2, varscan2
- ZNF737 | c.423A>T p.Q141H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV101417674; called by muse, mutect2, varscan2
- ACADSB | c.62C>G p.T21S | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRA2 | c.2906_2914del p.A969_E971del | In Frame Del (DEL) | VAF 50/296 reads (17%) | called by mutect2, pindel, varscan2
- ADSL | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 152/673 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ALMS1 | c.11915C>T p.S3972L | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- APEX2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ASPM | c.9662G>T p.R3221M | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN1 | c.3382G>A p.D1128N | Missense Mutation (SNP) | VAF 127/348 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP2C2 | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 85/474 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B4 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BCAN | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- BCR | c.3697G>A p.D1233N | Missense Mutation (SNP) | VAF 123/711 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, varscan2
- BCS1L | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 120/445 reads (27%) | called by muse, mutect2, varscan2
- BLK | c.1478T>A p.F493Y | Missense Mutation (SNP) | VAF 211/473 reads (45%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- C2orf16 | c.2409G>C p.K803N | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- C2orf16 | c.2540G>A p.R847K | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CACNA1B | c.4382A>G p.Q1461R | Missense Mutation (SNP) | VAF 102/295 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CACNA1I | c.6653C>A p.A2218D | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CACNG6 | c.605G>C p.R202T (on ENST00000252729 / NM_145814.1; = p.R131T on NM_031897.2) | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- CAMSAP1 | c.3239C>G p.S1080C | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CARNMT1 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD300C | c.173G>T p.R58I | Missense Mutation (SNP) | VAF 128/359 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CD99L2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CDC42BPB | c.2977G>C p.E993Q | Missense Mutation (SNP) | VAF 41/347 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, varscan2
- CDH12 | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 46/201 reads (23%) | called by muse, mutect2, varscan2
- CDX2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 115/164 reads (70%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CEP350 | c.3892G>A p.D1298N | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CFAP54 | c.4688C>G p.S1563* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- CFAP54 | c.9011C>G p.S3004* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- CLEC11A | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 120/506 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP3 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- COL22A1 | c.3073-2A>T p.X1025_splice | Splice Site (SNP) | VAF 51/348 reads (15%) | called by muse, varscan2
- COX10 | c.691A>T p.I231F | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- DBF4B | c.540G>C p.R180S | Missense Mutation (SNP) | VAF 49/383 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- DISP1 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 125/384 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- DMD | c.5305C>A p.H1769N | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- DMXL2 | c.8648A>G p.D2883G | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DNAAF2 | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DNAH6 | c.5092G>C p.D1698H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNC2H1 | c.10762-1G>A p.X3588_splice | Splice Site (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- EIF4A1 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 98/617 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ELAVL4 | c.14T>A p.I5N | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ENTPD8 | c.1032del p.L345Cfs*18 (on ENST00000371506 / NM_001033113.2; = p.L345Cfs*65 on NM_198585.3) | Frame Shift Del (DEL) | VAF 46/280 reads (16%) | called by mutect2, varscan2
- EPHA10 | c.2849A>T p.Y950F | Missense Mutation (SNP) | VAF 166/674 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHA10 | c.2848T>G p.Y950D | Missense Mutation (SNP) | VAF 164/669 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH6B | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EVX2 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 150/598 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83F | c.750C>G p.D250E | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXW2 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 105/219 reads (48%) | called by muse, mutect2, varscan2
- FERMT1 | c.633G>C p.L211F | Missense Mutation (SNP) | VAF 1861/2423 reads (77%) | SIFT tolerated (0.38); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FNDC1 | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GANC | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 35/126 reads (28%) | PolyPhen benign (0.17); called by muse, mutect2, varscan2
- GKAP1 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 51/279 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by mutect2, varscan2
- GLDC | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 493/617 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- GM2A | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 199/677 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by mutect2, varscan2
- H1-6 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 161/241 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- H2BC1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- HIVEP3 | c.4258G>A p.G1420R | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- HJURP | c.2029C>G p.Q677E | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HNF1B | c.89T>A p.L30* | Nonsense Mutation (SNP) | VAF 179/894 reads (20%) | called by muse, varscan2
- INSR | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- IQGAP2 | c.1864T>G p.W622G | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ITGA2B | c.2842-4C>T | Splice Region (SNP) | VAF 109/613 reads (18%) | called by muse, mutect2, varscan2
- KANSL1 | c.1199_1221del p.S400Wfs*5 | Frame Shift Del (DEL) | VAF 38/312 reads (12%) | called by mutect2, pindel
- KCNN2 | c.808G>T p.A270S (on ENST00000264773; = p.A482S on NM_021614.4) | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- KHDC4 | c.764C>A p.P255Q | Missense Mutation (SNP) | VAF 140/774 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIAA1109 | c.587G>A p.W196* | Nonsense Mutation (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2
- KIAA1210 | c.4445G>T p.R1482I | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- KIAA1549 | c.4471_4506del p.M1491_P1502del | In Frame Del (DEL) | VAF 120/552 reads (22%) | called by mutect2, pindel
- KIDINS220 | c.4990G>A p.E1664K | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- KISS1R | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 114/408 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LENG8 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- LMOD2 | c.619A>C p.K207Q | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRIT1 | c.477C>G p.F159L | Missense Mutation (SNP) | VAF 221/743 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- LRRC7 | c.3788C>T p.A1263V (on ENST00000651989 / NM_001370785.2; = p.A1230V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MAGEA12 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 134/503 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MAGEC1 | c.52T>A p.S18T | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.153); called by mutect2, varscan2
- MAGI3 | c.1408C>G p.H470D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCHR2 | c.699T>A p.D233E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MINK1 | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 99/259 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MORC4 | c.881T>C p.M294T | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MS4A1 | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- MTARC2 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MTREX | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC17 | c.1990A>G p.T664A | Missense Mutation (SNP) | VAF 57/1032 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- MUC5B | c.4496G>A p.G1499D | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MVP | c.1730C>G p.S577C | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH7B | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 174/254 reads (69%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.056); called by muse, varscan2
- MYT1L | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 83/620 reads (13%) | called by muse, mutect2
- NAV3 | c.5707G>A p.D1903N (on ENST00000397909 / NM_001024383.2; = p.D1881N on NM_014903.6) | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- NFE2L2 | c.101_103del p.R34_E35delinsQ | In Frame Del (DEL) | VAF 46/235 reads (20%) | called by mutect2, pindel, varscan2
- NOXO1 | c.437C>T p.P146L (on ENST00000397280 / NM_172168.3; = p.P140L on NM_144603.4) | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR10AG1 | c.274A>G p.M92V | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR4P4 | c.149C>A p.T50N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- OR5B3 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR5T2 | c.1030T>G p.F344V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR8K3 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ORC4 | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PALB2 | c.109-1G>C p.X37_splice | Splice Site (SNP) | VAF 91/479 reads (19%) | called by muse, mutect2, varscan2
- PALM3 | c.1180G>A p.E394K (on ENST00000340790; = p.E409K on NM_001145028.2) | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- PAN3 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGB6 | c.1284del p.K429Sfs*46 | Frame Shift Del (DEL) | VAF 50/235 reads (21%) | called by mutect2, pindel, varscan2
- PDE1C | c.426-1G>C p.X142_splice | Splice Site (SNP) | VAF 75/157 reads (48%) | called by muse, mutect2, varscan2
- PDE6D | c.292A>C p.I98L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PDSS2 | c.1094G>C p.C365S | Missense Mutation (SNP) | VAF 108/431 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PLD2 | c.1722G>C p.K574N | Missense Mutation (SNP) | VAF 132/345 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PLEKHM1 | c.3035C>G p.P1012R | Missense Mutation (SNP) | VAF 77/530 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNCK | c.-1C>A | Splice Region (SNP) | VAF 48/198 reads (24%) | called by muse, varscan2
- PON2 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- PP2D1 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PPIL4 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PPP1R14D | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 44/272 reads (16%) | called by muse, mutect2, varscan2
- PRDM9 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 110/397 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS36 | c.1838G>C p.R613P | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PSG11 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 120/265 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PTK2 | c.1521G>C p.L507= | Splice Region (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- PTPN14 | c.3540C>G p.F1180L | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PTPN3 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.222); called by muse, varscan2
- RALGDS | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 114/655 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- RBM25 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.67); called by muse, varscan2
- RBM6 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- RECQL4 | c.2801G>T p.W934L | Missense Mutation (SNP) | VAF 110/937 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- REELD1 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RELA | c.8-20_12delinsC p.X3_splice | Splice Site (DEL) | VAF 20/66 reads (30%) | called by pindel, varscan2*
- RNF148 | c.865del p.L289Ffs*2 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- SBNO2 | c.4059C>G p.I1353M | Missense Mutation (SNP) | VAF 110/595 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SCCPDH | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCN11A | c.4387A>T p.R1463* | Nonsense Mutation (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- SCN1A | c.429_430del p.F144Yfs*5 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by pindel, varscan2
- SCN3A | c.4585G>T p.D1529Y | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEMA7A | c.709_714del p.D237_D238del | In Frame Del (DEL) | VAF 26/154 reads (17%) | called by mutect2, pindel, varscan2
- SLC12A5 | c.3411C>G p.I1137M (on ENST00000454036 / NM_001134771.2; = p.I1114M on NM_020708.5) | Missense Mutation (SNP) | VAF 169/354 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- SLC15A2 | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- SLC22A12 | c.1318C>A p.L440M | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SLC22A6 | c.775T>C p.F259L | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SLC25A39 | c.728G>A p.W243* (on ENST00000377095 / NM_001143780.3; = p.W235* on NM_016016.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 53/482 reads (11%) | called by muse, mutect2
- SLC4A7 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- SON | c.4774A>T p.T1592S | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SP3 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SPATA17 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 62/425 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN2 | c.5998G>A p.E2000K | Missense Mutation (SNP) | VAF 131/526 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SULT1C3 | c.731A>C p.N244T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYNGAP1 | c.3487C>T p.H1163Y | Missense Mutation (SNP) | VAF 139/581 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TBC1D19 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TCN2 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TCOF1 | c.1536G>A p.M512I (on ENST00000377797 / NM_001135243.1; = p.M435I on NM_000356.4) | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THAP4 | c.1104G>C p.K368N | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TLE3 | c.2003G>A p.C668Y | Missense Mutation (SNP) | VAF 82/308 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM232 | c.1643C>A p.T548K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- TMEM8B | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TP53 | c.455_474del p.P152Rfs*22 | Frame Shift Del (DEL) | VAF 345/524 reads (66%) | called by mutect2, pindel, varscan2
- TPH2 | c.409C>G p.P137A | Missense Mutation (SNP) | VAF 135/602 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPK1 | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TRPC6 | c.2010A>T p.T670= | Splice Region (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- TRPC6 | c.2010-1G>T p.X670_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- TUB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/201 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- USP42 | c.3877G>T p.E1293* | Nonsense Mutation (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- VPS13D | c.5280G>C p.L1760F | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- VPS4B | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR97 | c.4286G>A p.G1429E | Missense Mutation (SNP) | VAF 102/786 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- YWHAH | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 122/502 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ZAN | c.6923C>T p.S2308F | Missense Mutation (SNP) | VAF 1029/1480 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZBTB11 | c.1826G>T p.S609I | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ZBTB20 | c.1213G>A p.E405K (on ENST00000474710 / NM_001164342.2; = p.E332K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 181/288 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZBTB41 | c.1839C>G p.I613M | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF121 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF134 | c.1089G>C p.Q363H | Missense Mutation (SNP) | VAF 101/464 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF219 | c.1897del p.A633Qfs*115 | Frame Shift Del (DEL) | VAF 101/352 reads (29%) | called by mutect2, pindel, varscan2
- ZNF506 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ZNF57 | c.1125_1151del p.W375_R384delins* | Nonsense Mutation (DEL) | VAF 46/246 reads (19%) | called by mutect2, pindel
- ZNF587 | c.367G>C p.G123R | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF646 | c.4663G>C p.D1555H | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF804A | c.1783A>G p.R595G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ZRANB3 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 66/377 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRD1 | c.1386G>T p.L462= | Silent (SNP) | VAF 76/195 reads (39%) | catalogued as COSV55455056; called by muse, mutect2, varscan2
- ADSL | c.723G>A p.Q241= | Silent (SNP) | VAF 41/299 reads (14%) | called by muse, mutect2, varscan2
- ALMS1 | c.2562C>G p.T854= | Silent (SNP) | VAF 86/236 reads (36%) | called by muse, mutect2, varscan2
- ANKS4B | c.1182A>G p.K394= | Silent (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- AP3B1 | c.1929G>A p.A643= | Silent (SNP) | VAF 99/360 reads (28%) | catalogued as rs745776425; called by muse, mutect2, varscan2
- ARFGEF2 | c.4992G>A p.R1664= | Silent (SNP) | VAF 81/407 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.1569G>C p.P523= | Silent (SNP) | VAF 56/171 reads (33%) | called by muse, mutect2, varscan2
- ASPM | c.9663G>A p.R3221= | Silent (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2943G>T p.L981= (on ENST00000545399 / NM_001256214.2; = p.L968= on NM_152296.5) | Silent (SNP) | VAF 90/395 reads (23%) | called by muse, mutect2, varscan2
- C1orf100 | c.16C>T p.L6= | Silent (SNP) | VAF 105/385 reads (27%) | called by muse, mutect2, varscan2
- CACNA1I | c.6654C>G p.A2218= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- CAMKK1 | c.474C>T p.V158= | Silent (SNP) | VAF 89/277 reads (32%) | catalogued as COSV99339940; called by muse, mutect2, varscan2
- CD2BP2 | c.1025G>A p.*342= | Silent (SNP) | VAF 49/205 reads (24%) | called by muse, mutect2, varscan2
- CEMIP | c.216C>G p.V72= | Silent (SNP) | VAF 179/746 reads (24%) | called by muse, mutect2, varscan2
- CEMIP | c.339C>T p.L113= | Silent (SNP) | VAF 138/586 reads (24%) | catalogued as COSV99585788; called by muse, mutect2, varscan2
- CFAP65 | c.3318C>T p.P1106= | Silent (SNP) | VAF 208/347 reads (60%) | called by muse, mutect2, varscan2
- CHAC1 | c.141C>T p.F47= | Silent (SNP) | VAF 83/414 reads (20%) | catalogued as rs922731000; called by muse, mutect2, varscan2
- CLTC | c.1473C>T p.C491= | Silent (SNP) | VAF 41/238 reads (17%) | called by muse, mutect2, varscan2
- COL6A5 | c.2859A>G p.V953= | Silent (SNP) | VAF 204/383 reads (53%) | catalogued as rs747237205; called by muse, mutect2, varscan2
- CRISPLD2 | c.1122A>G p.K374= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- CYP51A1 | c.252G>T p.G84= | Silent (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- DAW1 | c.483C>G p.L161= | Silent (SNP) | VAF 36/145 reads (25%) | called by muse, mutect2, varscan2
- DCHS1 | c.1836C>G p.L612= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- DHX16 | c.1803G>A p.Q601= | Silent (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- DNAH5 | c.13368C>T p.F4456= | Silent (SNP) | VAF 74/302 reads (25%) | catalogued as COSV99446000; called by muse, mutect2
- DPH3 | c.30C>T p.I10= | Silent (SNP) | VAF 62/227 reads (27%) | catalogued as COSV53265227; called by muse, mutect2, varscan2
- ECT2L | c.2178T>C p.H726= | Silent (SNP) | VAF 35/209 reads (17%) | called by muse, mutect2, varscan2
- EPHB2 | c.2241G>T p.L747= (on ENST00000400191 / NM_001309193.2; = p.L748= on NM_004442.7) | Silent (SNP) | VAF 135/642 reads (21%) | called by muse, mutect2, varscan2
- EPS15L1 | c.84G>A p.P28= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs778115246, COSV50168239; called by muse, mutect2, varscan2
- EXD3 | c.1107C>G p.P369= | Silent (SNP) | VAF 91/499 reads (18%) | called by muse, mutect2, varscan2
- FADS2 | c.114C>G p.V38= | Silent (SNP) | VAF 121/499 reads (24%) | called by muse, mutect2, varscan2
- GALR1 | c.597C>A p.A199= | Silent (SNP) | VAF 200/309 reads (65%) | called by muse, mutect2, varscan2
- GGNBP2 | c.534T>C p.C178= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- GRM1 | c.1137C>T p.R379= | Silent (SNP) | VAF 216/451 reads (48%) | called by muse, mutect2, varscan2
- H3C2 | c.192G>A p.R64= | Silent (SNP) | VAF 159/712 reads (22%) | catalogued as rs1177773736, COSV52519062, COSV99451251; called by muse, mutect2, varscan2
- HIF1AN | c.69C>A p.L23= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV54501546; called by muse, mutect2, varscan2
- HS3ST6 | c.762C>T p.S254= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs375144140; called by muse, mutect2, varscan2
- HSD17B3 | c.144A>G p.G48= | Silent (SNP) | VAF 116/512 reads (23%) | called by muse, mutect2, varscan2
- IFNL3 | c.342C>T p.A114= | Silent (SNP) | VAF 84/570 reads (15%) | called by muse, mutect2, varscan2
- IL31 | c.60C>T p.G20= | Silent (SNP) | VAF 137/285 reads (48%) | catalogued as rs768265104; called by muse, mutect2, varscan2
- INTS1 | c.5970C>T p.F1990= | Silent (SNP) | VAF 43/204 reads (21%) | catalogued as rs138397380, COSV67177289; called by muse, mutect2, varscan2
- ISL1 | c.285C>T p.A95= | Silent (SNP) | VAF 151/494 reads (31%) | catalogued as COSV100045374; called by muse, mutect2, varscan2
- KCNG3 | c.105G>C p.V35= | Silent (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- KMT2C | c.3618G>A p.L1206= | Silent (SNP) | VAF 130/325 reads (40%) | called by muse, mutect2, varscan2
- KNL1 | c.3372C>T p.N1124= (on ENST00000346991 / NM_170589.5; = p.N1098= on NM_144508.5) | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as rs372010989; called by muse, mutect2, varscan2
- KRT5 | c.1698C>A p.G566= | Silent (SNP) | VAF 28/236 reads (12%) | called by muse, mutect2
- KRT72 | c.609C>T p.N203= | Silent (SNP) | VAF 90/380 reads (24%) | called by muse, mutect2, varscan2
- KRT8 | c.672C>T p.L224= | Silent (SNP) | VAF 116/601 reads (19%) | catalogued as rs748339103; called by muse, mutect2, varscan2
- MAPK7 | c.363G>T p.L121= | Silent (SNP) | VAF 58/279 reads (21%) | called by muse, mutect2, varscan2
- MMP16 | c.744G>T p.L248= | Silent (SNP) | VAF 47/245 reads (19%) | called by muse, mutect2, varscan2
- MRM3 | c.807G>C p.L269= | Silent (SNP) | VAF 76/408 reads (19%) | called by muse, mutect2, varscan2
- MRPL3 | c.1020C>T p.P340= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs146622166; called by muse, mutect2, varscan2
- NKX2-1 | c.483C>T p.R161= | Silent (SNP) | VAF 218/957 reads (23%) | called by muse, mutect2, varscan2
- OR51M1 | c.555C>G p.V185= | Silent (SNP) | VAF 94/568 reads (17%) | catalogued as COSV60784257, COSV60785544; called by muse, mutect2, varscan2
- OR5B2 | c.252T>A p.L84= | Silent (SNP) | VAF 112/232 reads (48%) | called by muse, mutect2, varscan2
- PEG10 | c.846G>A p.T282= (on ENST00000482108 / NM_001040152.2; = p.T316= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 142/1172 reads (12%) | catalogued as COSV71788049; called by muse, mutect2, varscan2
- PLTP | c.1479C>G p.V493= | Silent (SNP) | VAF 57/222 reads (26%) | called by muse, mutect2, varscan2
- PRKG2 | c.2157G>A p.L719= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV52331625; called by muse, mutect2, varscan2
- PRMT1 | c.1029C>T p.N343= | Silent (SNP) | VAF 54/239 reads (23%) | called by muse, mutect2, varscan2
- RASAL3 | c.2934G>A p.L978= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV54604595; called by muse, mutect2, varscan2
- RBM25 | c.1014G>A p.E338= | Silent (SNP) | VAF 82/296 reads (28%) | catalogued as rs780600489, COSV56203454; called by muse, varscan2
- RFX6 | c.1230G>A p.V410= | Silent (SNP) | VAF 95/451 reads (21%) | called by muse, mutect2, varscan2
- RUNDC3A | c.1230C>G p.L410= | Silent (SNP) | VAF 65/383 reads (17%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.87G>A p.T29= | Silent (SNP) | VAF 32/476 reads (7%) | catalogued as rs200755602, COSV101193394, COSV66426134; called by muse, mutect2
- SHANK2 | c.543G>A p.K181= | Silent (SNP) | VAF 122/1522 reads (8%) | called by muse, mutect2
- SHROOM1 | c.2421C>T p.D807= (on ENST00000378679 / NM_001172700.2; = p.D802= on NM_133456.2) | Silent (SNP) | VAF 158/540 reads (29%) | called by muse, mutect2, varscan2
- SLC22A25 | c.87C>A p.V29= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV100123750, COSV60594248; called by muse, mutect2, varscan2
- SLC5A11 | c.648C>T p.L216= | Silent (SNP) | VAF 43/237 reads (18%) | catalogued as rs775074754, COSV61740899; called by muse, mutect2, varscan2
- SMARCAL1 | c.2757C>T p.S919= | Silent (SNP) | VAF 100/366 reads (27%) | called by muse, mutect2, varscan2
- SMTNL2 | c.351C>T p.S117= | Silent (SNP) | VAF 98/467 reads (21%) | called by muse, mutect2, varscan2
- SPACA1 | c.663T>C p.F221= | Silent (SNP) | VAF 52/205 reads (25%) | called by muse, mutect2, varscan2
- SPATA20 | c.288G>A p.K96= (on ENST00000356488 / NM_001258372.1; = p.K112= on NM_022827.4) | Silent (SNP) | VAF 73/455 reads (16%) | catalogued as rs1293950768; called by muse, mutect2, varscan2
- SPECC1L | c.2694G>A p.L898= | Silent (SNP) | VAF 110/354 reads (31%) | called by muse, mutect2, varscan2
- TBC1D10B | c.1968C>T p.S656= | Silent (SNP) | VAF 87/380 reads (23%) | called by muse, mutect2, varscan2
- TCHHL1 | c.1497A>T p.T499= | Silent (SNP) | VAF 66/455 reads (15%) | catalogued as COSV64285229; called by muse, mutect2, varscan2
- TIMM10B | c.168G>A p.L56= | Silent (SNP) | VAF 62/318 reads (19%) | catalogued as COSV99601626; called by muse, mutect2, varscan2
- TRPV5 | c.1347G>A p.G449= | Silent (SNP) | VAF 87/278 reads (31%) | called by muse, mutect2, varscan2
- TTC39C | c.1647A>G p.L549= (on ENST00000317571 / NM_001135993.2; = p.L488= on NM_153211.4) | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- TTN | c.45645C>T p.P15215= (on ENST00000591111; = p.P7791= on NM_003319.4) | Silent (SNP) | VAF 45/223 reads (20%) | called by muse, mutect2, varscan2
- UBR1 | c.3543G>A p.Q1181= | Silent (SNP) | VAF 99/472 reads (21%) | called by muse, mutect2, varscan2
- UBR5 | c.7353A>T p.A2451= | Silent (SNP) | VAF 53/342 reads (15%) | called by muse, mutect2, varscan2
- VSTM2A | c.489G>A p.S163= | Silent (SNP) | VAF 126/2923 reads (4%) | catalogued as rs376317939, COSV56494785; called by muse, mutect2
- WDR97 | c.4287G>C p.G1429= | Silent (SNP) | VAF 102/779 reads (13%) | catalogued as rs1482229000; called by muse, mutect2, varscan2
- ZFP92 | c.864C>T p.G288= | Silent (SNP) | VAF 527/607 reads (87%) | called by muse, mutect2, varscan2
- ZNF347 | c.1548T>C p.N516= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as rs1385263411; called by muse, mutect2, varscan2
- ZNF449 | c.312G>C p.L104= | Silent (SNP) | VAF 95/273 reads (35%) | called by muse, mutect2, varscan2
- ZNF551 | c.1302C>T p.L434= | Silent (SNP) | VAF 128/276 reads (46%) | called by muse, mutect2, varscan2
- ZNF708 | c.117C>T p.N39= | Silent (SNP) | VAF 39/207 reads (19%) | called by muse, mutect2, varscan2
- ZNF724 | c.1263C>G p.P421= | Silent (SNP) | VAF 131/339 reads (39%) | called by muse, mutect2, varscan2
- ZNF878 | c.327A>G p.E109= | Silent (SNP) | VAF 60/322 reads (19%) | called by muse, mutect2, varscan2
- ABCC6 | c.219+18G>A | Intron (SNP) | VAF 105/418 reads (25%) | catalogued as rs1478250868; called by muse, mutect2, varscan2
- AC092691.1 | n.353A>C | RNA (SNP) | VAF 84/309 reads (27%) | called by muse, mutect2, varscan2
- AGBL4 | c.1267+17C>T | Intron (SNP) | VAF 94/347 reads (27%) | catalogued as rs773299911; called by muse, mutect2, varscan2
- AGPAT2 | c.-24_-1del | 5'UTR (DEL) | VAF 122/555 reads (22%) | called by mutect2, pindel, varscan2
- ALDH1L1 | c.858+39C>G | Intron (SNP) | VAF 262/432 reads (61%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.128-842G>A | Intron (SNP) | VAF 58/233 reads (25%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505482 del GCGGGCAACCACTTTTCCCTAGCTTTTCCAG | 5'Flank (DEL) | VAF 10/110 reads (9%) | called by mutect2, pindel
- APLP1 | c.-20G>C | 5'UTR (SNP) | VAF 62/342 reads (18%) | called by muse, mutect2, varscan2
- APP | c.1687+8682G>T | Intron (SNP) | VAF 43/247 reads (17%) | called by muse, mutect2, varscan2
- ATP1A2 | c.117+32C>T | Intron (SNP) | VAF 109/320 reads (34%) | catalogued as rs1225449700; called by muse, mutect2, varscan2
- B4GALT1 | c.*39G>T | 3'UTR (SNP) | VAF 234/357 reads (66%) | catalogued as COSV101123016; called by muse, mutect2, varscan2
- BCS1L | c.719+18C>G | Intron (SNP) | VAF 114/401 reads (28%) | called by muse, mutect2, varscan2
- C12orf75 | c.-38G>T | 5'UTR (SNP) | VAF 32/137 reads (23%) | catalogued as rs991845072; called by muse, mutect2, varscan2
- CAPN14 | c.*28G>A | 3'UTR (SNP) | VAF 79/348 reads (23%) | catalogued as rs747405571; called by muse, mutect2, varscan2
- CCDC171 | c.-43C>G | 5'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- CCT5 | chr5:10249991 G>C | 5'Flank (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- CD3E | c.-46G>T | 5'UTR (SNP) | VAF 86/356 reads (24%) | catalogued as COSV62346210; called by muse, mutect2, varscan2
- CFAP45 | c.-49G>C | 5'UTR (SNP) | VAF 50/231 reads (22%) | called by muse, mutect2, varscan2
- CHCHD3 | c.525-18977G>T | Intron (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- CHTF8 | chr16:69132528 G>T | 5'Flank (SNP) | VAF 85/335 reads (25%) | called by muse, mutect2, varscan2
- COMMD4P1 | n.342G>T | RNA (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- COMMD9 | chr11:36271728 C>T | 3'Flank (SNP) | VAF 43/265 reads (16%) | called by muse, mutect2, varscan2
- DAP3 | c.994-39C>G | Intron (SNP) | VAF 60/299 reads (20%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+351G>A | Intron (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102275C>T | Intron (SNP) | VAF 48/277 reads (17%) | called by muse, mutect2, varscan2
- HTR3A | c.*20_*26delinsA | 3'UTR (DEL) | VAF 87/242 reads (36%) | called by pindel, varscan2*
- KMT5B | c.821-12G>C | Intron (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- LANCL2 | c.-10C>G | 5'UTR (SNP) | VAF 620/690 reads (90%) | catalogued as rs1181900761; called by muse, mutect2, varscan2
- LINC01135 | n.214C>A | RNA (SNP) | VAF 83/395 reads (21%) | called by muse, mutect2, varscan2
- LIPI | c.*9C>T | 3'UTR (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- LYRM4 | c.207+29761C>T | Intron (SNP) | VAF 10/55 reads (18%) | catalogued as rs994254082; called by muse, mutect2, varscan2
- MAD1L1 | c.1999-22597G>A | Intron (SNP) | VAF 104/344 reads (30%) | called by muse, mutect2, varscan2
- MAP2K3 | c.49+6648C>A | Intron (SNP) | VAF 12/304 reads (4%) | catalogued as rs1386067589; called by muse, mutect2
- MAP3K3 | c.126+1907A>G | Intron (SNP) | VAF 121/351 reads (34%) | catalogued as rs1206822665; called by muse, mutect2, varscan2
- MIR372 | n.52G>A | RNA (SNP) | VAF 20/96 reads (21%) | catalogued as rs1430584044; called by muse, mutect2, varscan2
- MIR622 | n.86G>C | RNA (SNP) | VAF 162/272 reads (60%) | called by muse, mutect2, varscan2
- MIR6859-4 | chr16:17008 T>C | 3'Flank (SNP) | VAF 60/1046 reads (6%) | called by muse, mutect2
- MYADML | n.1078C>A | RNA (SNP) | VAF 107/597 reads (18%) | called by muse, mutect2, varscan2
- MYOM1 | c.4685+114A>C | Intron (SNP) | VAF 43/167 reads (26%) | called by muse, mutect2, varscan2
- NPHP1 | c.70-970G>C | Intron (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- NXN | c.820+63G>A | Intron (SNP) | VAF 99/548 reads (18%) | called by muse, mutect2, varscan2
- OR52A4P | n.589G>A | RNA (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2
- PEX13 | c.92+379C>A | Intron (SNP) | VAF 55/309 reads (18%) | called by muse, mutect2, varscan2
- PML | c.1710+1448G>A | Intron (SNP) | VAF 170/739 reads (23%) | called by muse, mutect2, varscan2
- POU2F2 | c.*70G>A | 3'UTR (SNP) | VAF 69/154 reads (45%) | catalogued as rs578085962; called by muse, mutect2, varscan2
- PXDNL | c.*9T>G | 3'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- PYCR3 | c.*801C>T | 3'UTR (SNP) | VAF 75/694 reads (11%) | called by muse, mutect2, varscan2
- RIMS2 | c.4064-21217G>A | Intron (SNP) | VAF 232/397 reads (58%) | called by muse, mutect2, varscan2
- SREBF1 | c.1069-50C>T | Intron (SNP) | VAF 46/228 reads (20%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.579C>T | RNA (SNP) | VAF 46/208 reads (22%) | catalogued as rs758426906; called by muse, mutect2, varscan2
- STXBP5 | c.2080+1471C>G | Intron (SNP) | VAF 31/193 reads (16%) | called by muse, mutect2, varscan2
- SULF1 | c.*531T>C | 3'UTR (SNP) | VAF 93/295 reads (32%) | called by muse, mutect2, varscan2
- TMEM132D | c.1444-24C>A | Intron (SNP) | VAF 5/93 reads (5%) | catalogued as COSV67160974; called by muse, mutect2
- TRBV20-1 | c.-29G>C | 5'UTR (SNP) | VAF 79/417 reads (19%) | catalogued as rs759842361; called by muse, mutect2, varscan2
- UNC5D | c.*2523C>T | 3'UTR (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- ZNF252P | chr8:145003143 G>A | 5'Flank (SNP) | VAF 171/737 reads (23%) | called by muse, mutect2, varscan2
- ZNF549 | c.-64G>A | 5'UTR (SNP) | VAF 129/625 reads (21%) | catalogued as COSV53727717; called by muse, mutect2, varscan2
- ZNF670-ZNF695 | c.*237G>A | 3'UTR (SNP) | VAF 73/510 reads (14%) | called by muse, mutect2, varscan2
